Gene-level copy-number profile of tumor specimen TCGA-61-1721-01A from TCGA case TCGA-61-1721, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G1; Age at diagnosis: 38.0 years (13,894 days).
Specimen TCGA-61-1721-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.20c43493-7383-4650-a5f2-4a24759b53cb.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-61-1721-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5b48174e-6592-4dc3-b11b-3cf4ea776016

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 2: 59,820.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
